Surgical pathology report (de-identified scan), TCGA case TCGA-XD-AAUH, project TCGA-PAAD (Pancreatic Adenocarcinoma), tissue source site Providence Portland Medical Center, specimen TCGA-XD-AAUH-01A (Primary Tumor).

[page 1 of 5]
Collection date and time

ICD-O-3
Adenocarcinoma, duct NOS 8500/3
Site: Pancreas head C25.0
Op 5/21/14

Clinical Information

Obstruction of bile duct. Acute pancreatitis.

Diagnosis

A. LIVER CORE BIOPSY:

- Liver tissue with features consistent with bile outflow obstruction.
- No evidence of malignancy.

B. LIVER, WEDGE BIOPSY:

- Hyalinized nodule and features of bile outflow obstruction.
- No evidence of malignancy.

C. COMMON HEPATIC ARTERY LYMPH NODE, BIOPSY:

- Three lymph nodes with no evidence of malignancy (0/3).

D. PARTIAL PANCREATICODUODENECTOMY:

- Invasive moderately to poorly differentiated ductal adenocarcinoma, size: 2.8 cm in maximum diameter, invading into peripancreatic tissue and wall of small bowel, please see staging summary.
- Seven of twenty-two lymph nodes positive for metastatic carcinoma (7/22).
- Perineural invasion identified.
- Common bile duct, pancreatic duct margin and SMA margin negative for malignancy.
- Proximal duodenal margin positive for subserosal ductal adenocarcinoma, distal duodenal margin negative.

E. LYMPH NODE FROM AORTOCAVAL GROOVE, BIOPSY:

- Four lymph nodes with no evidence of malignancy (0/5).

Pathology Synoptic

Specimen type: Partial pancreaticoduodenectomy

Tumor location: Head of pancreas

Histologic type: Ductal adenocarcinoma

Histologic grade: G2-3

Tumor size and invasion of:

Tumor extends beyond the pancreas, but without involvement of

[page 2 of 5]
celiac axis or SMA: Yes

Tumor involves celiac axis or SMA: No

Lymphatic invasion: Identified

Large vessel invasion: Not identified

Margins:

Common bile duct: Negative

Proximal duodenal: Positive

Distal duodenal margin: Negative

Proximal or distal pancreatic margin: Negative

Peripancreatic soft tissue margin (including retroperitoneal and posterior pancreatic margin): Negative

Total regional lymph nodes: 30 Number positive: 7

AJCC Pathologic Stage: pT3 N1 (AJCC 7th edition, 2010)

Dictated and authenticated by:

Performing Location:

Gross Description

A. CORE LIVER BIOPSY

Received fresh labeled with the patient name

Description: The specimen consists of two cylinders of tan-brown tissue having lengths of 0.7 and 1.2 cm and diameters of less than 0.1 cm. The specimen is entirely embedded for a frozen section diagnosis.

FROZEN SECTION DIAGNOSIS PERFORMED AT
of malignancy.

No evidence

SECTIONS:

A1. Frozen section control.

B. WEDGE LIVER BIOPSY

Received fresh labeled with the patient name

Description: The specimen consists of three pieces of tan-brown tissue ranging from 0.5-1.0 cm in greatest dimension, each of which reveals a white-tan nodule measuring up to 0.1 cm in greatest specimen. The specimen is entirely embedded for a frozen section diagnosis.

FROZEN SECTION DIAGNOSIS PERFORMED AT
of malignancy.

No evidence

SECTIONS:

B1. Frozen section control.

[page 3 of 5]
C. COMMON HEPATIC ARTERY LYMPH NODE

Received in formalin labeled with the patient name

Description: The specimen consists of an irregular piece of yellow-brown tissue measuring 3.1 cm in greatest dimension, from which are retrieved three lymph nodes which are submitted in their entirety.

SECTIONS:

C1. One longitudinally bisected lymph node

C2. One intact lymph node and one inked and longitudinally bisected lymph node.

D. PRODUCT OF PARTIAL PANCREATODUODENECTOMY:

Received fresh labeled with the patient name

Specimen received: Product of a partial pancreaticoduodenectomy

Orientation given: Two medium length sutures, one long suture and two long sutures identify the bile duct, pancreatic neck and SMA margin respectively, per the intraoperative consultation form.

Integrity: The pancreatic component is intact; the duodenum is unopened.

Size of pancreas: 6.5 x 6.0 x 3.5 cm

Length of duodenum: 19.0 cm

Ducts: Probe patency cannot be demonstrated between the common bile duct and the ampulla.

Ampulla: The ampulla is easily probed from the pancreatic duct.

Inking scheme: The anterior and posterior surfaces of the pancreas are inked blue and black respectively. The margins of the common bile duct and the pancreas are inked purple and green respectively, after the true pancreatic margin is embedded for a frozen section diagnosis. The concavity created by the portal vein is inked yellow and the SMA margin is inked orange.

Tumor site: Within the head of the pancreas

Tumor size: Tumor is estimated to measure 2.8 cm in greatest dimension.

Tumor description: White-tan, waxy, poorly circumscribed

Invasion of: The tumor surrounds the common bile duct, compressing it to a diameter of less than 0.1 cm, having a diameter of 1.7 cm at its margin of resection.

Distance from margins: The tumor appears to most closely approximate the pancreatic margin of resection by 0.5 cm, the bile duct margin by 3.0 cm, the anterior blue ink aspect of the pancreas by apparently less than 0.1 cm, the posterior pancreas by 1.0 cm, the concavity created by the portal vein by 0.5 cm and the SMA margin by 1.0 cm.

Remaining specimen: The small intestinal component has stapled margins of resection, scant serosal adhesions, an average wall thickness of 0.3 cm and an unremarkable mucosa. Peripheral to the tumor the pancreas reveals unremarkable cut surfaces, excepting for a 1.1 cm smooth-walled cyst.

Lymph nodes: The lymph nodes retrieved from the specimen are submitted in their entirety.

Representative sections are submitted with the pancreatic component being submitted proceeding from the margin towards head.

FROZEN SECTION DIAGNOSIS PERFORMED AT

Indicated

margins: All negative for carcinoma.

SECTIONS:

D1. Frozen section control of common bile duct margin

D2. Frozen section control of pancreatic margin

D3. Frozen section control of SMA margin

D4-5. En face proximal and distal duodenal margins, respectively

[page 4 of 5]
- D6-7. Longitudinally bisected ampulla
- D8-9. Transverse of common bile duct proceeding from margin towards head with adjacent pancreatic tissue (green ink does not represent a true surgical margin)
- D10. Approximation of tumor to blue inked anterior pancreatic surface, duodenal wall and green inked cut surface of pancreas
- D11. Approximation of tumor to concavity created by portal vein including pancreatic cyst and beginning of stricture of common bile duct
- D12. Pancreatic cyst, SMA margin and the posterior surface of pancreas
- D13. Compressed bile duct and posterior surface of pancreas
- D14. Tumor and anterior surface of pancreas
- D15. Pancreas, SMA margin, posterior surface and one bisected lymph node
- D16. Pancreatic tissue and adjacent duodenal wall, posterior surface of pancreas and compressed common bile duct
- D17. Tumor, anterior surface of pancreas and pancreatic duct
- D18. Two inked and longitudinally bisected lymph nodes retrieved from anterior surface of pancreas
- D19-20. Eight intact lymph nodes retrieved from inferior aspect of pancreas with four in each cassette
- D21. Three intact lymph nodes retrieved from inferior aspect of pancreas
- D22. Two longitudinally bisected lymph nodes retrieved from inferior pancreas with one inked orange
- D23. One trisected lymph node retrieved from inferior aspect of pancreas
- D24-26. One sectioned lymph node retrieved from anterior pancreas adjacent to common bile duct.

E. LYMPH NODE FROM AORTOCAVAL GROOVE

Received in formalin labeled with the patient name

Description: The specimen consists of an ovoid piece of tan tissue having a diameter of 2.5 cm from which are retrieved multiple suspected lymph nodes which are submitted in their entirety.

SECTIONS:

- E1. Four intact suspected lymph nodes
- E2-3. One longitudinally trisected lymph node.

Microscopic Description

- A. CORE LIVER BIOPSY: Microscopic examination is performed and supports the diagnosis above.
- B. WEDGE LIVER BIOPSY: Microscopic examination is performed and supports the diagnosis above.
- C. COMMON HEPATIC ARTERY LYMPH NODE: Microscopic examination is performed and supports the diagnosis above.
- D. PRODUCT OF PARTIAL PANCREATODUODENECTOMY: Microscopic examination is performed and supports the diagnosis above.
- E. LYMPH NODE FROM AORTOCAVAL GROOVE: Microscopic examination is performed and supports the diagnosis above.

[page 5 of 5]
Surg Path Non-Chartable Comment

— Diagnosis given directly to surgeon over telephone/speaker phone. (parts A and B)

Tumor QC block on part D.;

Edited by:

Source: NCI Genomic Data Commons file 51f1f5d8-a96e-4320-9968-07a2463d5f03 (TCGA-XD-AAUH.7547A833-EA2B-48ED-B779-D632A6869FA0.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).